Somatic mutation profile of tumor specimen TARGET-30-PARVZT-01A (aliquot TARGET-30-PARVZT-01A-01D) from TARGET case TARGET-30-PARVZT, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.1 years (782 days).
Specimen TARGET-30-PARVZT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62e1d0a7-9a8f-4384-a443-a7e4cf4d44ea.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARVZT-10A (Blood Derived Normal), aliquot TARGET-30-PARVZT-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/406e43ec-439c-4ce3-a98e-92c4f7eaaa75

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1A | c.3448G>A p.V1150I | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.541); catalogued as rs376365775, COSV64190950; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH2 | c.8010C>A p.S2670R | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.153); catalogued as COSV66726198; called by muse, mutect2, varscan2
